Gene-level copy-number profile of tumor specimen TCGA-D1-A3DH-01A from TCGA case TCGA-D1-A3DH, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IA; Tumor grade: G3; Age at diagnosis: 71.0 years (25,935 days).
Specimen TCGA-D1-A3DH-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-UCEC.b698ed44-9263-4ea7-9c55-0f3449c60bf7.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-D1-A3DH-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 816 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/3ebb25d4-da1d-46aa-bbd1-4d6977cad9c2

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 19; copy number 1: 1,758; copy number 2: 19,442; copy number 3: 18,180; copy number 4: 13,700; copy number 5: 1,737; copy number 6: 3,811; copy number 7: 137; copy number 8: 474; copy number 9: 28; copy number 10: 105; copy number 11: 44; copy number 12: 171; copy number 13: 56; copy number 14: 145.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-D1-A3DH-01A-11D-A19X-01): tumor purity 0.89, ploidy 3.28, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 13 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:141,167,257–141,208,376, 2 genes: RNU6-904P, RPS16P3.
- chr3:116,850,277–116,850,367, 1 gene: MIR4447.
- chr4:181,237,358–181,265,145, 2 genes: AC019235.1, LINC02500.
- chr7:110,108,031–110,534,757, 2 genes (within-gene range 0–2): AC073114.1, AC073114.2.
- chr11:84,545,131–84,800,701, 3 genes: HNRNPA1P72, AP000852.1, AP001825.1.
- chr12:99,647,753–99,650,114, 1 gene: FAM71C.
- chr17:142,789–191,587, 2 genes: DOC2B, LINC02091.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,160 genes in 21 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:27,217,369–28,426,719, 43 genes, copy number 8 (within-gene range 4–8): CAD, SLC30A3, DNAJC5G, TRIM54, UCN, MPV17, GTF3C2, GTF3C2-AS1, AC074117.1, EIF2B4, SNX17, ZNF513, PPM1G, FTH1P3, NRBP1, KRTCAP3, IFT172, AC074117.2, RNU6-986P, FNDC4, GCKR, C2orf16, ZNF512, AC074091.2, CCDC121, GPN1, AC074091.1, SUPT7L, SLC4A1AP, LINC01460, MRPL33, RBKS, BABAM2, MYG1P1, MIR4263, FAM133EP, AC096552.1, AC093690.1, RPL23AP34, FLJ31356, FOSL2, AC104695.3, AC104695.2.
- chr2:43,092,530–43,233,394, 6 genes, copy number 7 (within-gene range 4–7): LINC02580, AC010883.2, AC010883.3, ZFP36L2, LINC01126, AC010883.1.
- chr2:111,865,798–114,420,302, 84 genes, copy number 10 (broad region; genes not listed).
- chr3:89,047,442–103,630,912, 151 genes, copy number 7–8 (broad region; genes not listed).
- chr4:15,963,076–16,227,410, 4 genes, copy number 8 (within-gene range 5–8): PROM1, AC108063.2, TAPT1, AC108063.1.
- chr5:58,198–40,755,963, 627 genes, copy number 8–14 (within-gene range 3–14) (broad region; genes not listed).
- chr6:18,363,417–18,674,001, 5 genes, copy number 9: DDX18P3, IMPDH1P9, RNF144B, MIR548A1HG, MIR548A1.
- chr6:128,500,527–128,639,653, 4 genes, copy number 7: AL034349.1, EEF1DP5, Y_RNA, AL080315.1.
- chr6:137,867,214–137,972,522, 4 genes, copy number 10 (within-gene range 5–10): TNFAIP3, AL591468.1, LINC02528, LINC02865.
- chr6:143,298,770–143,450,695, 6 genes, copy number 8 (within-gene range 2–8): AL136116.2, AL136116.1, AL136116.3, AL031320.1, ADAT2, TUBB8P2.
- chr8:74,984,505–75,352,327, 4 genes, copy number 10 (within-gene range 6–10): CRISPLD1, AC100782.1, CASC9, LINC02886.
- chr8:110,105,076–111,040,372, 8 genes, copy number 10 (within-gene range 6–10): RPSAP48, AC073023.1, AC090819.1, AC025366.1, AP005357.1, NDUFB9P3, LINC01608, MTCO1P47.
- chr11:72,814,406–73,397,474, 14 genes, copy number 7 (within-gene range 4–7): ATG16L2, FCHSD2, RNU6-672P, AP002381.1, AP002761.2, AP002761.1, P2RY2, AP002761.4, OR8R1P, P2RY6, AP002761.3, ARHGEF17, RELT, AP000763.4.
- chr11:73,405,297–73,452,344, 2 genes, copy number 7: AP000763.3, AP000763.1.
- chr12:67,571,197–69,855,363, 61 genes, copy number 8 (within-gene range 5–8) (broad region; genes not listed).
- chr12:70,638,073–71,118,247, 6 genes, copy number 9 (within-gene range 5–9): PTPRR, FAHD2P1, Y_RNA, AC123905.1, AC025575.1, AC025575.2.
- chr17:212,389–2,303,785, 79 genes, copy number 8–11 (within-gene range 5–11) (broad region; genes not listed).
- chr17:2,405,562–3,037,741, 20 genes, copy number 8 (within-gene range 5–8): METTL16, AC006435.4, AC006435.5, RN7SL33P, EIF4A1P9, PAFAH1B1, SAMD11P1, AC015799.1, RN7SL608P, AC005696.2, AC005696.3, CLUH, MIR6776, AC005696.1, AC005696.4, CCDC92B, MIR1253, hsa-mir-1253, RAP1GAP2, AC015921.1.
- chr17:9,244,666–9,822,071, 17 genes, copy number 9 (within-gene range 1–9): AC005695.3, STX8, AC005695.2, AC087501.1, AC087501.2, AC087501.3, AC087501.4, CFAP52, RPL19P18, AC118755.2, USP43, AC118755.1, AC027045.2, DHRS7C, AC027045.1, GSG1L2, AC027045.3.
- chr18:26,204,869–26,657,401, 12 genes, copy number 8: NPM1P2, TAF4B, SINHCAFP1, AC121320.1, AC022069.1, RNU6-1289P, LINC01543, KCTD1, AC007996.1, AC090206.1, MIR8057, CIAPIN1P.
- chr18:26,685,954–26,703,638, 3 genes, copy number 8: AC012588.1, PCAT18, U3.

Autosomal genes at a single copy (total copy number 1): 1,093. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
